Somatic mutation profile of tumor specimen TCGA-55-8507-01A (aliquot TCGA-55-8507-01A-11D-2393-08) from TCGA case TCGA-55-8507, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 53.1 years (19,390 days).
Specimen TCGA-55-8507-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 111dbfb4-baf4-49f8-be22-f7ff338167fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-8507-10A (Blood Derived Normal), aliquot TCGA-55-8507-10A-01D-2393-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1a6c1a4-c8f9-4ed6-9df0-85e7d5c2eadf

The open-access MAF lists 1,068 somatic variants for this specimen: 818 protein-altering or splice-affecting, 224 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 709, Silent 224, Nonsense Mutation 44, Frame Shift Del 29, Splice Site 24, RNA 16, Intron 9, Splice Region 8, In Frame Del 2, 3'Flank 1, Nonstop Mutation 1, Frame Shift Ins 1.

Variants (750 of 1,068; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGXT | c.943-1G>T p.X315_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as rs180177298, CS093822, COSV56756188; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DLD | c.1483A>G p.R495G | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121964989, CM960489, COSV99227265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FERMT1 | c.676del p.Q226Sfs*26 | Frame Shift Del (DEL) | VAF 14/74 reads (19%) | catalogued as rs748240859, COSV54090339; ClinVar: pathogenic; called by mutect2, varscan2
- GFAP | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 55/114 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267607510, CM077748, COSV99493389, COSV99493684; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 59/79 reads (75%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A1BG | c.91C>A p.L31M | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99568402; called by muse, mutect2, varscan2
- AAR2 | c.1117G>A p.V373M | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100299350; called by muse, mutect2, varscan2
- ABCA9 | c.96G>T p.L32F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV60629797; called by muse, mutect2
- ABCC11 | c.2716T>G p.C906G | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV100750894; called by muse, mutect2, varscan2
- ABCG2 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99419489; called by muse, mutect2, varscan2
- AC004593.2 | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV99765372; called by muse, mutect2, varscan2
- ACAD8 | c.778G>C p.G260R | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99844416; called by muse, mutect2, varscan2
- ACTA1 | c.125A>T p.H42L | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV100796759; called by muse, mutect2, varscan2
- ADAM19 | c.1510A>G p.T504A | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.381); catalogued as COSV57432096; called by muse, mutect2, varscan2
- ADAM7 | c.1520G>C p.R507P | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV99444241; called by muse, mutect2, varscan2
- ADAMTS1 | c.1553T>G p.V518G | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99536283; called by muse, mutect2, varscan2
- ADAMTS18 | c.1603G>T p.G535C | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99273312; called by muse, mutect2, varscan2
- ADAMTS20 | c.1074T>A p.T358= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as COSV101239590; called by muse, mutect2, varscan2
- ADAMTS6 | c.640A>G p.R214G | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1295007237, COSV101125172; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1671G>T p.Q557H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99443517; called by muse, mutect2, varscan2
- ADARB1 | c.1721G>T p.S574I (on ENST00000360697 / NM_001346687.2; = p.S534I on NM_001112.4) | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100653932; called by muse, mutect2, varscan2
- ADCY10 | c.1651C>T p.H551Y | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.24); PolyPhen benign (0.188); catalogued as COSV100896926; called by muse, mutect2, varscan2
- ADCY8 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs541460563, COSV99651514; called by muse, mutect2, varscan2
- ADK | c.867A>G p.I289M (on ENST00000286621; = p.I272M on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99692673; called by muse, mutect2, varscan2
- ADRA2C | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100342702; called by muse, mutect2, varscan2
- AFF2 | c.3712C>G p.R1238G | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53981655, COSV99664742; called by muse, mutect2
- AHNAK | c.9151C>T p.L3051F | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as rs1020256590, COSV99948108; called by muse, mutect2, varscan2
- AHNAK | c.2316C>A p.N772K | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV99948110; called by muse, mutect2, varscan2
- AKNAD1 | c.64del p.D22Tfs*7 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | catalogued as rs773216905; called by mutect2, pindel, varscan2
- ALB | c.1521C>G p.N507K | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.198); catalogued as COSV99891687; called by muse, mutect2, varscan2
- ALOX5 | c.187G>T p.G63C | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780433165, COSV100980090; called by muse, mutect2, varscan2
- ALOX5 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100980092, COSV65554848; called by muse, mutect2, varscan2
- ALPK2 | c.3185G>T p.S1062I | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100864506; called by muse, mutect2, varscan2
- ALPK2 | c.640G>T p.G214W | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100864507; called by muse, mutect2, varscan2
- AMER3 | c.2420del p.G807Afs*11 | Frame Shift Del (DEL) | VAF 5/31 reads (16%) | catalogued as COSV58466039; called by mutect2, pindel
- AMY2B | c.142G>C p.A48P | Missense Mutation (SNP) | VAF 66/145 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1258720765, COSV100796357; called by muse, mutect2, varscan2
- ANGPT4 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV101124774; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7400C>G p.S2467C | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.293); catalogued as rs1363867068, COSV99783709; called by muse, mutect2, varscan2
- ANKRD53 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs782343220, COSV99721447; called by muse, varscan2
- ANO4 | c.1859G>A p.G620E (on ENST00000392977 / NM_001286615.2; = p.G585E on NM_178826.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153114; called by muse, mutect2, varscan2
- ANO5 | c.401A>C p.H134P | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM137895, COSV100201969; called by muse, mutect2, varscan2
- ANO7 | c.1123G>T p.V375L (on ENST00000274979; = p.V321L on NM_001370694.2) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.022); catalogued as COSV99238726; called by muse, mutect2, varscan2
- AP1B1 | c.2443G>T p.A815S | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV100434533, COSV100434652; called by muse, mutect2, varscan2
- AP5M1 | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.132); catalogued as COSV99841155, COSV99841264; called by muse, mutect2, varscan2
- APC2 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99279588; called by muse, mutect2, varscan2
- APOB | c.380C>A p.S127Y | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99266292; called by muse, mutect2, varscan2
- ARHGAP11B | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV101451806, COSV70288354; called by muse, mutect2, varscan2
- ARHGAP17 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV51505511; called by muse, mutect2, varscan2
- ARHGEF12 | c.1866G>T p.Q622H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV100754998; called by muse, mutect2, varscan2
- ARSD | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs772412380, COSV99472201; called by muse, mutect2, varscan2
- ARSG | c.859G>T p.V287F | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV101477905; called by muse, mutect2, varscan2
- ASB15 | c.1190G>T p.R397M | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99306715; called by muse, mutect2, varscan2
- ASB2 | c.710A>C p.E237A | Missense Mutation (SNP) | VAF 13/288 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.029); catalogued as COSV100279405; called by muse, mutect2
- ASIC4 | c.1120G>T p.G374C (on ENST00000347842 / NM_182847.3; = p.G393C on NM_018674.6) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99705063; called by muse, mutect2, varscan2
- ASPHD2 | c.421G>T p.G141C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313428; called by muse, mutect2, varscan2
- ASPM | c.5585A>G p.K1862R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.261); catalogued as COSV99660626; called by muse, mutect2, varscan2
- ASTN1 | c.592G>T p.A198S | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.825); catalogued as COSV99922206; called by muse, mutect2, varscan2
- ATAD5 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.162); catalogued as COSV100430039; called by muse, mutect2
- ATG2B | c.2331G>T p.K777N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100738090; called by muse, mutect2, varscan2
- ATG9B | c.790G>T p.A264S | Missense Mutation (SNP) | VAF 49/216 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100939898; called by muse, mutect2, varscan2
- ATIC | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs776539487, COSV99377915; called by muse, mutect2, varscan2
- ATP10A | c.2856G>A p.M952I | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV100791354; called by muse, mutect2, varscan2
- ATP10D | c.3658G>T p.G1220C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV56712759; called by muse, mutect2, varscan2
- ATP1B1 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63170907; called by muse, mutect2, varscan2
- ATP6AP1 | c.742C>G p.Q248E | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.98); PolyPhen benign (0.001); catalogued as COSV100870706; called by muse, mutect2, varscan2
- ATP8B2 | c.2778T>A p.C926* (on ENST00000672630; = p.C893* on NM_001367934.1 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/455 reads (11%) | catalogued as COSV100528070; called by muse, mutect2, varscan2
- ATP9B | c.1934G>A p.R645K | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as COSV56959276; called by muse, mutect2, varscan2
- ATP9B | c.1935G>T p.R645S | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV100303755; called by muse, mutect2, varscan2
- AURKC | c.823A>T p.R275* (on ENST00000302804 / NM_001015878.2; = p.R241* on NM_003160.3) | Nonsense Mutation (SNP) | VAF 28/77 reads (36%) | catalogued as COSV100248896; called by muse, mutect2, varscan2
- BAIAP3 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100181644; called by muse, mutect2, varscan2
- BCHE | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100012737; called by muse, mutect2, varscan2
- BEND4 | c.1501G>C p.G501R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101549767; called by muse, mutect2, varscan2
- BIRC6 | c.4742G>C p.R1581T | Missense Mutation (SNP) | VAF 49/74 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101428422; called by muse, mutect2, varscan2
- BPIFB3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as rs1438069274, COSV100972450, COSV64956852; called by muse, mutect2
- BRINP2 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.21); catalogued as COSV100838060, COSV100838162; called by muse, mutect2, varscan2
- BRIP1 | c.993G>T p.M331I | Missense Mutation (SNP) | VAF 64/127 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.073); catalogued as COSV99370445; called by muse, mutect2, varscan2
- BTNL8 | c.1076G>T p.R359L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV51458332, COSV99180501; called by muse, mutect2, varscan2
- C10orf88 | c.661A>G p.I221V | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV100925030; called by muse, mutect2, varscan2
- C1orf94 | c.1672C>A p.P558T (on ENST00000488417 / NM_001134734.2; = p.P368T on NM_032884.5) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.117); catalogued as rs1435113532, COSV100975031; called by muse, mutect2, varscan2
- C1orf94 | c.1673C>A p.P558H (on ENST00000488417 / NM_001134734.2; = p.P368H on NM_032884.5) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as rs747669743, COSV100975033; called by muse, mutect2, varscan2
- C20orf96 | c.287C>T p.A96V (on ENST00000360321 / NM_153269.3; = p.A95V on NM_080571.1) | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV100826746; called by muse, mutect2, varscan2
- C7orf33 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as COSV100188840; called by muse, mutect2
- C8orf74 | c.603C>A p.F201L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV100262137; called by muse, mutect2, varscan2
- CA14 | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99354440; called by muse, mutect2, varscan2
- CACNA1I | c.2739C>G p.H913Q | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100360703; called by muse, mutect2, varscan2
- CADM1 | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402969579; called by muse, mutect2, varscan2
- CADM2 | c.301C>T p.Q101* (on ENST00000407528 / NM_001167674.2; = p.Q103* on NM_153184.4) | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as rs1209520053, COSV101057030; called by muse, mutect2
- CASK | c.191G>T p.S64I | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated (0.16); PolyPhen benign (0.176); catalogued as COSV100587371; called by muse, mutect2, varscan2
- CASP6 | c.637G>A p.A213T | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.259); catalogued as COSV99488738; called by muse, mutect2, varscan2
- CATSPER1 | c.1544-1G>T p.X515_splice | Splice Site (SNP) | VAF 14/36 reads (39%) | catalogued as COSV100376036; called by muse, mutect2, varscan2
- CBWD5 | c.112C>G p.L38V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.028); catalogued as COSV101070728; called by mutect2, varscan2
- CCDC136 | c.2791G>T p.E931* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV99922761; called by muse, mutect2, varscan2
- CCDC171 | c.3480G>T p.Q1160H | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52646711; called by muse, mutect2, varscan2
- CCDC28B | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.282); catalogued as COSV99356658; called by muse, mutect2, varscan2
- CCDC81 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV53579527; called by muse, mutect2, varscan2
- CCKBR | c.533C>T p.T178M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100582994; called by muse, mutect2, varscan2
- CCT8L2 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100742847; called by muse, mutect2, varscan2
- CDC20B | c.1279C>A p.R427S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as rs142234339, COSV99697054; called by muse, mutect2, varscan2
- CDH11 | c.415C>A p.L139M | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV99218874; called by muse, mutect2
- CDH18 | c.581G>T p.S194I | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56916875, COSV99936011; called by muse, mutect2, varscan2
- CDH22 | c.1562G>T p.S521I | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV100952904; called by muse, mutect2, varscan2
- CDH23 | c.4624G>C p.G1542R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV99821883, COSV99823372; called by muse, mutect2
- CEACAM20 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as COSV100386934; called by muse, mutect2
- CEACAM8 | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99747673; called by muse, mutect2, varscan2
- CEMIP2 | c.3956-1G>T p.X1319_splice | Splice Site (SNP) | VAF 6/13 reads (46%) | catalogued as rs750414679; called by mutect2, varscan2
- CEP250 | c.1967C>G p.A656G | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.559); catalogued as COSV100699008; called by muse, mutect2, varscan2
- CEP63 | c.442G>T p.E148* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV59677354; called by muse, mutect2, varscan2
- CES5A | c.1220T>G p.L407R | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99307706; called by muse, mutect2, varscan2
- CFAP44 | c.1427T>A p.V476E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99869879; called by muse, mutect2, varscan2
- CFAP91 | c.1812G>T p.E604D | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.859); catalogued as COSV99847224; called by muse, mutect2, varscan2
- CHD6 | c.7664C>A p.S2555* | Nonsense Mutation (SNP) | VAF 30/193 reads (16%) | catalogued as rs1378017668, COSV100950839, COSV100951161; called by muse, mutect2, varscan2
- CHD7 | c.1526A>T p.Q509L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.932); catalogued as COSV101418303; called by muse, mutect2, varscan2
- CHMP4B | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99459882; called by muse, mutect2, varscan2
- CHPF | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as rs142415191, COSV60534550, COSV60535493; called by muse, mutect2, varscan2
- CHRM2 | c.750C>A p.S250R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs964339453, COSV100281534; called by muse, mutect2, varscan2
- CHRM3 | c.532G>T p.A178S | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99698721; called by muse, mutect2, varscan2
- CHST8 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 57/90 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99381259; called by muse, mutect2, varscan2
- CLASP2 | c.2410G>T p.V804F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV100223692; called by muse, mutect2, varscan2
- CLCN4 | c.156G>T p.K52N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV101073895; called by muse, mutect2, varscan2
- CLIP2 | c.2942C>A p.P981H | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.188); catalogued as COSV99791780; called by muse, mutect2, varscan2
- CLNK | c.533del p.P178Lfs*26 | Frame Shift Del (DEL) | VAF 14/56 reads (25%) | catalogued as rs1332651871, COSV57018143; called by mutect2, pindel, varscan2
- CLSPN | c.1501G>T p.G501* | Nonsense Mutation (SNP) | VAF 22/103 reads (21%) | catalogued as COSV99231113; called by muse, mutect2, varscan2
- CLUH | c.3306G>C p.E1102D (on ENST00000435359; = p.E1141D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.05); catalogued as COSV101425791; called by muse, mutect2, varscan2
- CMIP | c.1552G>T p.V518L (on ENST00000537098 / NM_198390.2; = p.V424L on NM_030629.3) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); catalogued as COSV104432631, COSV67700867; called by muse, mutect2
- CNGB3 | c.1275G>C p.L425F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV60695665; called by muse, mutect2, varscan2
- CNGB3 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs762804298, COSV100182277; called by muse, mutect2, varscan2
- CNTLN | c.289G>T p.A97S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.199); catalogued as COSV99264611; called by mutect2, varscan2
- CNTN1 | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV100751116; called by muse, mutect2, varscan2
- CNTN1 | c.2014A>C p.I672L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.062); catalogued as COSV100751566; called by muse, mutect2, varscan2
- CNTNAP2 | c.1163G>C p.G388A | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV100667719, COSV62140404; called by muse, mutect2, varscan2
- CNTNAP5 | c.2532T>C p.S844= | Splice Region (SNP) | VAF 14/82 reads (17%) | catalogued as COSV101443733, COSV104436465; called by muse, mutect2
- COG2 | c.490C>G p.L164V | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100794710; called by muse, mutect2, varscan2
- COL11A1 | c.2299G>T p.A767S | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as COSV100617125; called by muse, mutect2, varscan2
- COL16A1 | c.1304del p.G435Efs*26 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | catalogued as COSV99057191; called by mutect2, pindel, varscan2
- COL1A1 | c.1462-1G>T p.X488_splice | Splice Site (SNP) | VAF 4/8 reads (50%) | catalogued as COSV99867527; called by muse, mutect2, varscan2
- COL1A2 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV99800190; called by muse, mutect2
- COL22A1 | c.2400G>C p.K800N | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as COSV100279022; called by muse, varscan2
- COL22A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs767596054, COSV100279026; called by muse, mutect2, varscan2
- COL2A1 | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.967); catalogued as COSV100476799, COSV61528769; called by muse, mutect2, varscan2
- COL4A1 | c.3154G>T p.A1052S | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.41); PolyPhen benign (0.396); catalogued as COSV101011276; called by muse, mutect2, varscan2
- COL4A1 | c.3153G>T p.Q1051H | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV101011277; called by muse, mutect2, varscan2
- COL6A3 | c.4120G>A p.D1374N | Missense Mutation (SNP) | VAF 58/110 reads (53%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); catalogued as COSV99799245; called by muse, mutect2, varscan2
- COPB1 | c.2091G>C p.M697I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV51450077, COSV99999690; called by muse, mutect2, varscan2
- CPS1 | c.3956G>T p.R1319M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV99243342; called by muse, mutect2, varscan2
- CRB1 | c.2696del p.G899Efs*89 | Frame Shift Del (DEL) | VAF 47/199 reads (24%) | catalogued as COSV66329886; called by mutect2, pindel, varscan2
- CRB2 | c.404C>A p.P135H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100749694, COSV63503990; called by muse, mutect2, varscan2
- CREBBP | c.1045G>T p.E349* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV52137277; called by muse, mutect2, varscan2
- CRYBA2 | c.530A>T p.Y177F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.45); PolyPhen benign (0.062); catalogued as COSV99837929; called by muse, mutect2, varscan2
- CRYGC | c.142C>A p.R48S | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs201568695, COSV56408546; called by muse, mutect2
- CRYZ | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV100558638; called by muse, mutect2, varscan2
- CSH2 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs747513645, COSV100400260; called by mutect2, varscan2
- CSMD1 | c.2383C>A p.H795N (on ENST00000520002; = p.H794N on NM_033225.6) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100149902; called by muse, mutect2, varscan2
- CSMD2 | c.7970C>A p.S2657Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99591738; called by muse, mutect2, varscan2
- CSMD3 | c.6258T>A p.G2086= (on ENST00000297405 / NM_001363185.1; = p.G1982= on NM_052900.3) | Splice Region (SNP) | VAF 11/57 reads (19%) | catalogued as COSV99838131; called by muse, mutect2, varscan2
- CSMD3 | c.3115G>T p.G1039* (on ENST00000297405 / NM_001363185.1; = p.G935* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 22/131 reads (17%) | catalogued as COSV52324345; called by muse, mutect2, varscan2
- CSMD3 | c.2032G>T p.D678Y (on ENST00000297405 / NM_001363185.1; = p.D574Y on NM_052900.3) | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV99838134; called by muse, mutect2, varscan2
- CSMD3 | c.140G>T p.W47L | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.04); catalogued as COSV99838135; called by muse, mutect2, varscan2
- CT45A1 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as rs1180585216; called by muse, mutect2, varscan2
- DAB2 | c.703C>A p.L235M | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100297978; called by muse, mutect2, varscan2
- DCAF12L1 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 104/138 reads (75%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs757437493, COSV100948354; called by muse, mutect2, varscan2
- DCUN1D4 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100584573; called by muse, varscan2
- DDI1 | c.150G>A p.M50I | Missense Mutation (SNP) | VAF 66/295 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.076); catalogued as COSV100159715; called by muse, mutect2, varscan2
- DDR2 | c.1996C>G p.L666V | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100906637, COSV63372557; called by muse, mutect2, varscan2
- DDX27 | c.1645C>T p.H549Y | Missense Mutation (SNP) | VAF 16/271 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100873371; called by muse, mutect2
- DENND5B | c.3638C>A p.T1213K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as COSV100171677; called by muse, mutect2, varscan2
- DGKB | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.364); catalogued as COSV51764144, COSV99340703; called by muse, mutect2, varscan2
- DGKH | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99819042; called by muse, mutect2, varscan2
- DIAPH2 | c.1804G>T p.G602* | Nonsense Mutation (SNP) | VAF 35/40 reads (88%) | catalogued as COSV100233520; called by muse, mutect2, varscan2
- DIAPH3 | c.624G>T p.V208= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as COSV99933829; called by muse, mutect2, varscan2
- DIP2A | c.3658G>A p.V1220M | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV100596013; called by muse, mutect2, varscan2
- DISP3 | c.3836A>G p.Q1279R | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.306); catalogued as COSV99609082; called by muse, mutect2, varscan2
- DLG5 | c.1661C>G p.A554G | Missense Mutation (SNP) | VAF 45/69 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100967587, COSV100967592; called by muse, mutect2, varscan2
- DLGAP2 | c.2372C>A p.T791N | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.156); catalogued as COSV101422189; called by muse, mutect2, varscan2
- DLL3 | c.785G>T p.G262V | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV99219234; called by muse, mutect2, varscan2
- DMBT1 | c.1768G>A p.G590S | Missense Mutation (SNP) | VAF 68/113 reads (60%) | SIFT tolerated (0.47); PolyPhen benign (0.395); catalogued as COSV100353299; called by muse, mutect2, varscan2
- DMBT1 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100353301, COSV57552174; called by muse, mutect2, varscan2
- DMBT1 | c.2329G>T p.G777C | Missense Mutation (SNP) | VAF 207/343 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353302; called by muse, mutect2, varscan2
- DNAH17 | c.2686G>A p.A896T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.245); catalogued as rs375761147; called by muse, mutect2, varscan2
- DNAH3 | c.10297C>G p.H3433D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV99768390; called by muse, mutect2, varscan2
- DNAH5 | c.13796C>G p.A4599G | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV99451111; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>C p.D3236H | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.475G>C p.G159R | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99451119; called by muse, mutect2, varscan2
- DNAH7 | c.5315C>T p.A1772V | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs748432820, COSV100415893; called by muse, mutect2, varscan2
- DNAH7 | c.2615C>T p.T872I | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100415897; called by muse, mutect2, varscan2
- DNAH9 | c.377C>A p.P126H | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV99306453; called by muse, mutect2, varscan2
- DNAH9 | c.5154G>T p.V1718= | Splice Region (SNP) | VAF 69/102 reads (68%) | catalogued as COSV99306455; called by muse, mutect2, varscan2
- DNAH9 | c.9070C>A p.Q3024K | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99306457; called by muse, mutect2, varscan2
- DNAJC11 | c.623G>C p.W208S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99602319; called by muse, mutect2
- DNAJC19 | c.184G>A p.E62K | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV100700320; called by muse, varscan2
- DNER | c.2119C>T p.R707W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201404779, COSV59167037; called by muse, mutect2, varscan2
- DRD3 | c.171G>T p.E57D | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as rs1179688666, COSV55678302, COSV99879522; called by muse, mutect2, varscan2
- DSC2 | c.701A>T p.E234V | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99199699; called by muse, mutect2, varscan2
- DSC3 | c.787G>T p.G263W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV64573620; called by muse, mutect2, varscan2
- DSEL | c.3511A>G p.T1171A | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100025793; called by muse, mutect2, varscan2
- DSG4 | c.2429G>C p.G810A | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100356036, COSV57394701; called by muse, mutect2, varscan2
- DST | c.14194G>C p.D4732H (on ENST00000361203 / NM_001374722.1; = p.D2320H on NM_015548.5) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99757587; called by muse, mutect2, varscan2
- DST | c.2756G>T p.R919L (on ENST00000361203 / NM_001374722.1; = p.R593L on NM_001723.6) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99757592; called by muse, mutect2, varscan2
- DVL2 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99138585; called by muse, mutect2, varscan2
- DYNC2H1 | c.12773G>A p.C4258Y | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100518894, COSV62098180; called by muse, mutect2, varscan2
- E2F2 | c.252G>A p.P84= | Splice Region (SNP) | VAF 13/51 reads (25%) | catalogued as rs777714546, COSV100674824, COSV100674842; called by muse, mutect2, varscan2
- EBF1 | c.1218C>A p.D406E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.323); catalogued as COSV100566014; called by muse, mutect2
- EBF3 | c.1435C>A p.Q479K (on ENST00000355311 / NM_001375392.1; = p.Q470K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.094); catalogued as COSV100799349, COSV62480854; called by muse, mutect2, varscan2
- EDIL3 | c.212A>T p.E71V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.266); catalogued as COSV56909397, COSV99677348; called by muse, mutect2, varscan2
- EGFLAM | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 154/256 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV100472173; called by muse, mutect2, varscan2
- ENPP2 | c.1649G>C p.R550T (on ENST00000075322 / NM_001040092.3; = p.R602T on NM_006209.5) | Missense Mutation (SNP) | VAF 49/207 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.05); catalogued as COSV99308637; called by muse, mutect2, varscan2
- EOMES | c.1161G>T p.M387I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99841927, COSV99842089; called by muse, mutect2, varscan2
- EP400 | c.6629C>T p.P2210L | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs746515682, COSV100201465; called by muse, varscan2
- EPB41L5 | c.329-1G>T p.X110_splice | Splice Site (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99758863; called by muse, mutect2, varscan2
- EPB42 | c.9G>T p.Q3H | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as COSV100282033, COSV55751694; called by muse, mutect2, varscan2
- EPHA3 | c.63A>T p.E21D | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100346264; called by muse, mutect2, varscan2
- EPHA3 | c.952C>A p.P318T | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.058); catalogued as COSV100346265, COSV60704539; called by muse, mutect2, varscan2
- EPHA7 | c.687G>T p.E229D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.94); catalogued as COSV65169251; called by muse, mutect2, varscan2
- EPHB2 | c.2719C>A p.R907S (on ENST00000400191 / NM_001309193.2; = p.R908S on NM_004442.7) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as COSV65860195; called by muse, mutect2, varscan2
- EPHX4 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs373441880; called by muse, mutect2, varscan2
- ESPNL | c.1457G>T p.R486M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV100547851; called by muse, mutect2, varscan2
- ESR1 | c.123G>T p.E41D | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as COSV99239719; called by muse, mutect2, varscan2
- ESX1 | c.745G>C p.V249L | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.031); catalogued as COSV101006478; called by muse, mutect2, varscan2
- EXO1 | c.52C>T p.H18Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100799938; called by muse, mutect2, varscan2
- EXOSC2 | c.122+1G>C p.X41_splice | Splice Site (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100964263; called by muse, mutect2, varscan2
- EZH2 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.373); catalogued as rs1263098237, COSV100235941; called by muse, mutect2, varscan2
- F12 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99499776; called by muse, mutect2
- F2RL2 | c.558C>A p.C186* | Nonsense Mutation (SNP) | VAF 7/44 reads (16%) | catalogued as COSV99167540; called by muse, mutect2, varscan2
- FAM135B | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs1449614480, COSV99425089; called by muse, mutect2, varscan2
- FAM83C | c.514-1G>T p.X172_splice | Splice Site (SNP) | VAF 39/114 reads (34%) | catalogued as COSV65584051; called by muse, mutect2, varscan2
- FAT3 | c.12721T>A p.F4241I | Missense Mutation (SNP) | VAF 118/295 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.948); catalogued as COSV99967374; called by muse, mutect2, varscan2
- FAT4 | c.7359T>G p.S2453R | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100629062; called by muse, mutect2, varscan2
- FBN2 | c.4288G>T p.G1430C | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52532841, COSV99328531; called by muse, mutect2, varscan2
- FBN2 | c.1743G>T p.Q581H | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.596); catalogued as COSV52530652, COSV99328535; called by muse, mutect2, varscan2
- FBXL7 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as rs754686344, COSV100310093; called by muse, mutect2, varscan2
- FBXO30 | c.188G>C p.S63T | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.308); catalogued as COSV99395258; called by muse, mutect2, varscan2
- FGA | c.1814A>C p.D605A | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.369); catalogued as COSV100120481; called by muse, mutect2, varscan2
- FGA | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 13/44 reads (30%) | catalogued as CM013713, COSV100120485; called by muse, mutect2, varscan2
- FGFR1OP2 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.937); catalogued as COSV99986933; called by muse, mutect2, varscan2
- FILIP1 | c.158G>T p.G53V | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as COSV99384167, COSV99385219; called by muse, mutect2, varscan2
- FLG | c.8516G>C p.R2839T | Missense Mutation (SNP) | VAF 67/637 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.172); catalogued as rs765709562, COSV64239335; called by muse, mutect2, varscan2
- FLG | c.5960G>T p.R1987L | Missense Mutation (SNP) | VAF 215/582 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as COSV100911689; called by muse, mutect2, varscan2
- FLG | c.5066C>T p.A1689V | Missense Mutation (SNP) | VAF 87/517 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.989); catalogued as COSV100911690; called by muse, mutect2, varscan2
- FNDC1 | c.2248G>C p.A750P | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.439); catalogued as COSV99796128, COSV99796243; called by muse, mutect2, varscan2
- FOXP2 | c.238G>T p.D80Y | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100646936; called by muse, mutect2, varscan2
- FOXR2 | c.293C>A p.P98H | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.931); catalogued as COSV100189537, COSV59257855; called by muse, mutect2, varscan2
- FPR2 | c.646A>G p.I216V | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.122); catalogued as COSV100389317; called by muse, mutect2, varscan2
- FREM1 | c.4322A>T p.Q1441L | Missense Mutation (SNP) | VAF 30/43 reads (70%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as COSV101084856; called by muse, mutect2, varscan2
- FRMPD2 | c.2306C>A p.P769Q | Missense Mutation (SNP) | VAF 45/68 reads (66%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.9); catalogued as COSV100563933, COSV59714868; called by muse, mutect2, varscan2
- FSD1 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV55698457; called by muse, mutect2, varscan2
- FSIP2 | c.16136G>T p.G5379V | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100555508; called by muse, mutect2
- FUCA2 | c.791G>T p.G264V | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136115; called by muse, mutect2, varscan2
- FUT5 | c.551G>T p.W184L | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.997); catalogued as COSV99398843; called by muse, mutect2, varscan2
- FZD10 | c.600C>A p.H200Q | Missense Mutation (SNP) | VAF 36/60 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV99969479; called by muse, mutect2, varscan2
- GABBR2 | c.2056C>T p.L686F | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99410482; called by muse, mutect2, varscan2
- GABRA2 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100734447, COSV100734861; called by muse, mutect2
- GABRA4 | c.1280C>T p.S427F | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.353); catalogued as COSV99974225; called by muse, mutect2, varscan2
- GABRA5 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100165377, COSV59478769; called by muse, mutect2, varscan2
- GABRD | c.951C>A p.C317* | Nonsense Mutation (SNP) | VAF 36/69 reads (52%) | catalogued as COSV101059554; called by muse, mutect2, varscan2
- GABRE | c.1154G>A p.R385H | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.654); catalogued as rs1453012053, COSV100944314; called by muse, mutect2, varscan2
- GABRG1 | c.149A>T p.N50I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99778297; called by muse, varscan2
- GABRG3 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs751413776, COSV100408192; called by muse, mutect2, varscan2
- GATM | c.1043-1G>T p.X348_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101188313; called by muse, mutect2, varscan2
- GIPC1 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs747831375, COSV100600104; called by muse, mutect2, varscan2
- GJA10 | c.1247G>C p.S416T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV101005380; called by muse, mutect2, varscan2
- GJA9 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668130; called by muse, mutect2
- GJB3 | c.384G>T p.W128C | Missense Mutation (SNP) | VAF 80/189 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100974023; called by muse, mutect2, varscan2
- GJD2 | c.689A>G p.E230G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99290797; called by muse, mutect2, varscan2
- GKAP1 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV100897670; called by muse, mutect2, varscan2
- GLUD2 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 58/93 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100046904; called by muse, mutect2, varscan2
- GOLGA4 | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 12/28 reads (43%) | catalogued as COSV100728991; called by muse, mutect2, varscan2
- GPC5 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.262); catalogued as rs748697208, COSV65597581, COSV65631670; called by muse, mutect2, varscan2
- GPR17 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99760679; called by muse, mutect2, varscan2
- GPR61 | c.14C>A p.P5H | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV101344409; called by muse, mutect2, varscan2
- GRAP2 | c.700G>T p.G234* | Nonsense Mutation (SNP) | VAF 25/105 reads (24%) | catalogued as COSV100703033; called by muse, mutect2, varscan2
- GRIA4 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 77/103 reads (75%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV99232061; called by muse, mutect2, varscan2
- GRIN2A | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as rs779149309, COSV100410258; called by muse, mutect2, varscan2
- GRIN2B | c.1595C>T p.T532I | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101663093; called by muse, mutect2, varscan2
- GRIN2C | c.2543C>A p.P848H | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.066); catalogued as COSV99501143; called by muse, mutect2, varscan2
- GRM8 | c.1870G>C p.V624L | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs368344634, COSV100279908, COSV100283900; called by muse, mutect2, varscan2
- GUCY1B1 | c.166A>T p.S56C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100025657, COSV52378967; called by muse, mutect2, varscan2
- GUF1 | c.1869A>C p.K623N | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99776978; called by muse, mutect2, varscan2
- HAUS5 | c.1719G>T p.R573S | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV99178772; called by muse, mutect2, varscan2
- HCFC1 | c.5981C>T p.A1994V | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100128564; called by muse, mutect2, varscan2
- HDX | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV99947537; called by muse, mutect2, varscan2
- HELZ | c.1131A>T p.Q377H | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100698837; called by muse, mutect2, varscan2
- HEPHL1 | c.2877T>A p.D959E | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV100244068; called by muse, mutect2, varscan2
- HMGCLL1 | c.1112G>T p.*371Lext*20 | Nonstop Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV51450197; called by muse, varscan2
- HMGCLL1 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99232518; called by muse, varscan2
- HMGCS2 | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as COSV101024837; called by muse, mutect2, varscan2
- HMGN4 | c.241C>T p.Q81* | Nonsense Mutation (SNP) | VAF 21/135 reads (16%) | catalogued as COSV101110242; called by muse, mutect2, varscan2
- HNF4A | c.163G>T p.G55C | Missense Mutation (SNP) | VAF 38/259 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100291495; called by muse, mutect2, varscan2
- HOOK3 | c.937G>T p.V313L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.525); catalogued as COSV100295629; called by muse, mutect2, varscan2
- HS3ST4 | c.489G>C p.E163D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.047); catalogued as COSV100501900; called by muse, mutect2
- HSD17B4 | c.1856G>T p.G619V (on ENST00000414835 / NM_001199291.3; = p.G594V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99819940; called by muse, mutect2, varscan2
- HSPA12A | c.1336G>T p.D446Y | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV100979855; called by muse, mutect2, varscan2
- HSPA2 | c.834C>A p.S278R | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99905015; called by muse, mutect2, varscan2
- HSPG2 | c.11548G>T p.D3850Y | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101013491; called by muse, mutect2, varscan2
- HTR1D | c.382C>T p.H128Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58449632; called by muse, mutect2, varscan2
- HTR7 | c.1091G>T p.W364L | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as COSV53284276; called by muse, mutect2, varscan2
- HTRA1 | c.1015G>T p.V339L | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100934765; called by muse, mutect2, varscan2
- ICAM5 | c.2159C>G p.A720G | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99703408; called by muse, mutect2, varscan2
- IGHD | c.107C>A p.T36K | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs376901676, COSV101162941, COSV66654942; called by muse, mutect2, varscan2
- IGKV3D-11 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs1390375904; called by muse, mutect2, varscan2
- IHH | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.192); catalogued as COSV99838715; called by muse, mutect2, varscan2
- IL2RA | c.783G>T p.W261C | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99906751; called by muse, mutect2, varscan2
- IL7R | c.515A>C p.E172A | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.095); catalogued as COSV100286374; called by muse, mutect2
- ILDR2 | c.748G>T p.V250F | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.406); catalogued as rs751139759, COSV99614026; called by muse, mutect2, varscan2
- INSC | c.815T>A p.L272* | Nonsense Mutation (SNP) | VAF 67/115 reads (58%) | catalogued as COSV101089322; called by muse, mutect2, varscan2
- INSRR | c.2788G>A p.G930R | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.889); catalogued as COSV100947683; called by muse, mutect2
- IPO11 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57578401; called by muse, mutect2, varscan2
- IQGAP3 | c.1256A>G p.Q419R | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV100752198; called by muse, mutect2
- IREB2 | c.980A>T p.N327I | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); catalogued as COSV99359526; called by muse, mutect2, varscan2
- IRF8 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV99236613; called by muse, mutect2, varscan2
- IRS4 | c.995G>C p.C332S | Missense Mutation (SNP) | VAF 124/184 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as COSV100929608; called by muse, mutect2, varscan2
- ITGA2 | c.1888G>T p.G630W | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99671047; called by muse, mutect2, varscan2
- ITGA2 | c.1889G>T p.G630V | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99671084; called by muse, mutect2, varscan2
- ITGA8 | c.2312A>T p.D771V | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.34); catalogued as COSV100959362; called by muse, mutect2, varscan2
- ITGA8 | c.2311G>A p.D771N | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as rs765711289, COSV100959364; called by muse, mutect2, varscan2
- ITGAV | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99655189; called by muse, mutect2, varscan2
- JAK3 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV101512969; called by muse, mutect2, varscan2
- JAM2 | c.130C>G p.Q44E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV100467633, COSV100468401; called by muse, mutect2, varscan2
- JMJD1C | c.5521G>T p.G1841* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100550651; called by muse, mutect2, varscan2
- JUND | c.654A>T p.E218D | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV99417242; called by muse, mutect2, varscan2
- KALRN | c.6133G>T p.E2045* (on ENST00000360013 / NM_001024660.4; = p.E348* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99362332; called by muse, mutect2, varscan2
- KANSL2 | c.252G>T p.G84= | Splice Region (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100770993; called by muse, mutect2
- KCND2 | c.1125C>A p.D375E | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100476704; called by muse, mutect2
- KCNG1 | c.1099G>A p.G367R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857120; called by muse, mutect2, varscan2
- KCNIP3 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99734269; called by muse, mutect2, varscan2
- KCNJ10 | c.188A>C p.Q63P | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV100927931; called by muse, mutect2, varscan2
- KCNT2 | c.3190G>T p.G1064C | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV99653820, COSV99654737; called by muse, mutect2, varscan2
- KCTD6 | c.561A>T p.E187D | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.341); catalogued as COSV100250212, COSV57151200; called by muse, mutect2, varscan2
- KDM4D | c.586A>T p.M196L | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV100624291, COSV100624416; called by muse, mutect2
- KHDRBS2 | c.934del p.D312Mfs*18 | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | catalogued as COSV55488606; called by mutect2, pindel, varscan2
- KIAA1549L | c.712C>A p.P238T (on ENST00000321505; = p.P535T on NM_012194.3) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.521); catalogued as COSV99683794; called by muse, mutect2, varscan2
- KIAA1614 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 63/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100851322; called by muse, mutect2, varscan2
- KIF26B | c.735G>A p.W245* | Nonsense Mutation (SNP) | VAF 10/28 reads (36%) | catalogued as COSV101313957; called by muse, mutect2, varscan2
- KIR3DL1 | c.34+1G>T p.X12_splice | Splice Site (SNP) | VAF 54/160 reads (34%) | catalogued as rs1233140019, COSV100428686; called by muse, mutect2, varscan2
- KLHL38 | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 62/186 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100384445, COSV58086288; called by muse, mutect2, varscan2
- KLK15 | c.341A>T p.Q114L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV100032795; called by muse, mutect2, varscan2
- KNTC1 | c.1551A>T p.R517S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100338462; called by muse, mutect2
- KPRP | c.339C>A p.C113* | Nonsense Mutation (SNP) | VAF 129/315 reads (41%) | catalogued as rs751837891, COSV100908732, COSV64222642; called by muse, mutect2, varscan2
- KRT37 | c.758T>A p.L253Q | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99845573; called by muse, mutect2, varscan2
- KRT72 | c.1121C>A p.A374D | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV53375680, COSV99537355; called by muse, mutect2, varscan2
- KRT84 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as rs1420869382, COSV99230926; called by muse, mutect2, varscan2
- KRTAP15-1 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as COSV100481633; called by muse, mutect2, varscan2
- KYNU | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99933456; called by muse, varscan2
- LAMA1 | c.8044G>T p.A2682S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.012); catalogued as rs1410590532, COSV101056771; called by muse, mutect2, varscan2
- LAMA1 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056774, COSV67545150; called by muse, mutect2, varscan2
- LAMB4 | c.3094A>T p.M1032L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99224565; called by muse, mutect2, varscan2
- LARGE1 | c.2019G>T p.R673S | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100505709; called by muse, mutect2, varscan2
- LARGE1 | c.2018G>T p.R673M | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100505716; called by muse, mutect2, varscan2
- LCE1F | c.72C>A p.C24* | Nonsense Mutation (SNP) | VAF 42/160 reads (26%) | catalogued as COSV100542740; called by muse, mutect2, varscan2
- LCE3E | c.259G>A p.G87S | Missense Mutation (SNP) | VAF 51/299 reads (17%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs760662720, COSV64231502; called by muse, mutect2, varscan2
- LCT | c.1519C>A p.H507N | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.109); catalogued as COSV51558865; called by muse, mutect2, varscan2
- LDB2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as rs1204888185, COSV58771153, COSV58772049; called by muse, mutect2, varscan2
- LDB2 | c.662A>T p.K221I | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100454024; called by muse, mutect2, varscan2
- LEXM | c.176G>T p.R59L | Missense Mutation (SNP) | VAF 70/243 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV100827652; called by muse, mutect2, varscan2
- LILRA1 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV52182079; called by muse, mutect2, varscan2
- LIPF | c.242T>A p.F81Y | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV99490370; called by muse, mutect2, varscan2
- LIPI | c.928T>C p.C310R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753789; called by muse, varscan2
- LIPI | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as COSV100753792, COSV60709176, COSV60709881; called by muse, varscan2
- LMO7 | c.1327G>C p.A443P (on ENST00000357063; = p.A173P on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100413465; called by muse, mutect2, varscan2
- LRBA | c.6225C>T p.A2075= | Splice Region (SNP) | VAF 25/58 reads (43%) | catalogued as rs201176491; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRFN1 | c.1365G>T p.Q455H | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV99953064; called by muse, mutect2, varscan2
- LRFN2 | c.248T>C p.L83P | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599667; called by muse, mutect2, varscan2
- LRP1 | c.2512G>T p.D838Y | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54509207, COSV99676286; called by muse, mutect2, varscan2
- LRP1 | c.8625G>T p.Q2875H | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV99676287; called by muse, mutect2, varscan2
- LRP1B | c.9836T>C p.I3279T | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV101257931; called by muse, mutect2, varscan2
- LRP1B | c.5258G>T p.G1753V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as COSV101257933; called by mutect2, varscan2
- LRP1B | c.3683G>A p.C1228Y | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101257934; called by muse, mutect2, varscan2
- LRP2 | c.1529G>C p.G510A | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (1); catalogued as COSV99789141; called by muse, mutect2, varscan2
- LRP5 | c.271T>C p.Y91H | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs1213838692, COSV53712223, COSV99592226; called by muse, mutect2, varscan2
- LRPAP1 | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 28/247 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99579014; called by muse, mutect2, varscan2
- LRRC20 | c.532G>T p.G178C (on ENST00000355790 / NM_207119.3; = p.G122C on NM_018205.4) | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV100714233; called by muse, mutect2, varscan2
- LRRC36 | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99338830; called by muse, mutect2, varscan2
- LRRC4C | c.1553G>T p.G518V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99538707; called by muse, mutect2, varscan2
- LRRC6 | c.1282G>T p.V428L | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.065); catalogued as COSV99138115; called by muse, mutect2, varscan2
- LRRC7 | c.114G>C p.E38D (on ENST00000651989 / NM_001370785.2; = p.E5D on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99227829; called by muse, mutect2, varscan2
- LRRTM1 | c.998A>T p.Q333L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV99702753; called by muse, mutect2, varscan2
- LSS | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710950; called by muse, mutect2, varscan2
- LTBP2 | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100000524; called by muse, mutect2, varscan2
- LUZP2 | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100419220; called by muse, mutect2, varscan2
- LYZL2 | c.499C>A p.Q167K (on ENST00000375318; = p.Q121K on NM_183058.3) | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs1222704942, COSV100940611; called by muse, mutect2, varscan2
- MAB21L2 | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100462243; called by muse, mutect2, varscan2
- MACF1 | c.78C>A p.Y26* | Nonsense Mutation (SNP) | VAF 53/135 reads (39%) | catalogued as COSV100485121; called by muse, mutect2, varscan2
- MAGEB6 | c.593A>C p.K198T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1405551697, COSV100983777; called by muse, mutect2, varscan2
- MAGEE1 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.213); catalogued as COSV100819432; called by muse, mutect2, varscan2
- MAK16 | c.234G>T p.W78C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100789446; called by muse, mutect2, varscan2
- MANBA | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.149); catalogued as rs1455710995; called by mutect2, varscan2
- MAP2 | c.3104A>T p.E1035V | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV99560627; called by muse, mutect2, varscan2
- MATK | c.1346G>T p.C449F (on ENST00000310132 / NM_139355.3; = p.C450F on NM_002378.4) | Missense Mutation (SNP) | VAF 49/76 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100036156; called by muse, mutect2, varscan2
- MBL2 | c.630G>T p.E210D | Missense Mutation (SNP) | VAF 55/209 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100906360; called by muse, mutect2, varscan2
- MCHR2 | c.296G>T p.W99L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99912256; called by muse, mutect2, varscan2
- MED12L | c.3212G>T p.C1071F | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99853669; called by muse, mutect2, varscan2
- MED13L | c.2512G>A p.G838R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as COSV99927541, COSV99929221; called by muse, mutect2, varscan2
- MED13L | c.1117C>T p.H373Y | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs1369725946, COSV99929222; called by muse, mutect2, varscan2
- MEGF11 | c.1694C>A p.T565K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.388); catalogued as COSV56559815, COSV99988281; called by muse, mutect2, varscan2
- MEIS1 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV99715384; called by muse, mutect2, varscan2
- METTL25 | c.1479-2A>T p.X493_splice | Splice Site (SNP) | VAF 4/12 reads (33%) | catalogued as COSV99942443; called by muse, mutect2
- MEX3A | c.406G>A p.V136I | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs1178733186, COSV100848987; called by muse, mutect2, varscan2
- MIB2 | c.2922G>T p.R974S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV61543394; called by muse, mutect2, varscan2
- MLF1 | c.280G>T p.G94C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV100576020; called by muse, mutect2, varscan2
- MLXIPL | c.1614G>T p.E538D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.931); catalogued as COSV100515414; called by muse, mutect2, varscan2
- MMEL1 | c.365G>T p.G122V | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99983985; called by muse, mutect2
- MMUT | c.1117G>T p.E373* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV51272800; called by muse, mutect2, varscan2
- MN1 | c.2883G>T p.K961N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.991); catalogued as COSV100179916; called by muse, mutect2, varscan2
- MOGAT3 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 93/199 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99777203; called by muse, mutect2, varscan2
- MORN1 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101045926; called by muse, mutect2, varscan2
- MPHOSPH6 | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99259261; called by muse, mutect2, varscan2
- MSTO1 | c.1222G>T p.G408* | Nonsense Mutation (SNP) | VAF 133/236 reads (56%) | catalogued as COSV99824258; called by muse, mutect2, varscan2
- MTFR1L | c.502T>C p.S168P | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as COSV100961890; called by muse, mutect2, varscan2
- MTMR14 | c.726C>A p.F242L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99931367; called by muse, mutect2, varscan2
- MTRES1 | c.491A>G p.Y164C | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.063); catalogued as rs1554228152, COSV100261203; called by muse, mutect2, varscan2
- MUC16 | c.36268G>T p.D12090Y | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV101200289; called by muse, mutect2, varscan2
- MUC16 | c.31158C>A p.S10386R | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as rs754424826, COSV101200290, COSV67469364; called by muse, mutect2, varscan2
- MUC3A | c.8404C>T p.P2802S | Missense Mutation (SNP) | VAF 80/230 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.035); catalogued as COSV100114822; called by muse, mutect2, varscan2
- MXRA5 | c.6028C>G p.L2010V | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760533583, COSV99477211, COSV99477669; called by muse, mutect2, varscan2
- MXRA5 | c.767G>A p.C256Y | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54231971; called by muse, mutect2, varscan2
- MYH13 | c.3145C>G p.R1049G | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.614); catalogued as COSV52837628, COSV99354446; called by muse, mutect2, varscan2
- MYH4 | c.3109G>T p.D1037Y | Missense Mutation (SNP) | VAF 114/172 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55113829, COSV99701560; called by muse, mutect2, varscan2
- MYH4 | c.664C>T p.Q222* | Nonsense Mutation (SNP) | VAF 48/72 reads (67%) | catalogued as COSV99701563; called by muse, mutect2, varscan2
- MYH4 | c.428A>T p.Y143F | Missense Mutation (SNP) | VAF 165/224 reads (74%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV55125645; called by muse, mutect2, varscan2
- MYH7 | c.764C>A p.T255K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV100806248; called by muse, mutect2, varscan2
- MYL1 | c.53C>A p.P18Q | Missense Mutation (SNP) | VAF 226/448 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV100751646; called by muse, mutect2, varscan2
- MYLK2 | c.890G>T p.G297V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65658735; called by muse, mutect2, varscan2
- MYO3A | c.3128A>T p.Y1043F | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99780264; called by muse, mutect2, varscan2
- MYO6 | c.2980G>T p.E994* | Nonsense Mutation (SNP) | VAF 59/195 reads (30%) | catalogued as COSV100889376; called by muse, mutect2, varscan2
- NAT8L | c.842C>G p.S281W | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100526998; called by muse, mutect2, varscan2
- NCAM2 | c.2203A>T p.I735F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV99523655; called by muse, mutect2, varscan2
- NCAN | c.2759G>A p.S920N | Missense Mutation (SNP) | VAF 91/158 reads (58%) | SIFT tolerated (0.35); PolyPhen benign (0.05); catalogued as COSV99387583; called by muse, mutect2, varscan2
- NCKAP5 | c.4361C>A p.A1454D | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs1345739425, COSV58441311, COSV58448724; called by muse, mutect2, varscan2
- NCR2 | c.112G>T p.V38L | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.377); catalogued as COSV100897237; called by muse, mutect2, varscan2
- NDUFAF1 | c.71del p.L24Cfs*48 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as COSV99531612; called by mutect2, pindel, varscan2
- NEB | c.8456G>C p.W2819S | Missense Mutation (SNP) | VAF 60/380 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99424623; called by muse, mutect2, varscan2
- NEB | c.4938C>A p.N1646K | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs765208384, COSV51434160, COSV99424626; called by muse, mutect2, varscan2
- NEK10 | c.2163G>C p.Q721H | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV99835333; called by muse, mutect2, varscan2
- NENF | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.265); catalogued as COSV100877092; called by muse, mutect2, varscan2
- NEO1 | c.307C>A p.L103I | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.074); catalogued as COSV99982328; called by muse, mutect2, varscan2
- NETO1 | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100199002; called by muse, mutect2, varscan2
- NEXMIF | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99281111; called by muse, mutect2, varscan2
- NFE2 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779667357, COSV56456769; called by muse, mutect2, varscan2
- NHS | c.1265G>T p.G422V | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101196722; called by muse, mutect2, varscan2
- NKAIN4 | c.55G>C p.V19L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.033); catalogued as COSV100941627; called by muse, mutect2, varscan2
- NKX3-2 | c.343G>C p.G115R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.031); catalogued as COSV101219924; called by muse, mutect2, varscan2
- NLRP11 | c.2116T>A p.F706I | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV100789765; called by muse, mutect2, varscan2
- NLRP13 | c.1205C>A p.S402* | Nonsense Mutation (SNP) | VAF 39/62 reads (63%) | catalogued as COSV100738326; called by muse, mutect2, varscan2
- NLRP3 | c.856C>G p.H286D | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV100276261, COSV60219343; called by muse, mutect2, varscan2
- NLRP3 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100276264; called by muse, mutect2, varscan2
- NLRP4 | c.2526-1G>T p.X842_splice | Splice Site (SNP) | VAF 57/102 reads (56%) | catalogued as COSV100016564; called by muse, mutect2, varscan2
- NLRP7 | c.2728T>A p.L910M (on ENST00000340844 / NM_206828.3; = p.L882M on NM_139176.3) | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100052912; called by muse, mutect2, varscan2
- NNT | c.2798A>G p.Y933C | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99239120; called by muse, mutect2, varscan2
- NPY2R | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV100279739, COSV100279772; called by muse, mutect2, varscan2
- NPY5R | c.775C>A p.L259I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV100642830; called by muse, mutect2, varscan2
- NSMAF | c.914G>T p.W305L | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99233118; called by muse, varscan2
- NUTM1 | c.1156G>C p.G386R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.885); catalogued as COSV100149069; called by muse, mutect2, varscan2
- NXF3 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 108/146 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV101222005; called by muse, mutect2, varscan2
- OLFM4 | c.706G>T p.V236F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV99524417; called by muse, mutect2, varscan2
- OR10AD1 | c.589C>A p.L197M | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV100046850; called by muse, mutect2, varscan2
- OR10H5 | c.137T>A p.M46K | Missense Mutation (SNP) | VAF 44/146 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as COSV100454724; called by muse, mutect2, varscan2
- OR10H5 | c.719C>G p.S240C | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100454727; called by muse, mutect2, varscan2
- OR10J1 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs889830723, COSV101419910; called by muse, mutect2, varscan2
- OR11H1 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV99421861; called by muse, mutect2, varscan2
- OR11H6 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100209863; called by muse, mutect2
- OR13A1 | c.804G>T p.M268I | Missense Mutation (SNP) | VAF 49/70 reads (70%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100981050; called by muse, mutect2, varscan2
- OR13F1 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV100594794; called by muse, mutect2, varscan2
- OR1Q1 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99939263; called by muse, mutect2, varscan2
- OR2A12 | c.859C>A p.L287I | Missense Mutation (SNP) | VAF 26/396 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.125); catalogued as COSV68821485; called by muse, mutect2
- OR2A5 | c.646G>T p.V216F | Missense Mutation (SNP) | VAF 142/280 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.098); catalogued as COSV101278779; called by muse, mutect2, varscan2
- OR2AK2 | c.410G>T p.S137I | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV100823955; called by muse, mutect2, varscan2
- OR2G6 | c.676T>G p.L226V | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.976); catalogued as COSV58573800; called by muse, mutect2
- OR2L8 | c.44G>T p.G15V | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100594020; called by muse, mutect2, varscan2
- OR2M2 | c.133A>T p.M45L | Missense Mutation (SNP) | VAF 55/306 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV62899674; called by muse, mutect2, varscan2
- OR2M4 | c.224G>T p.C75F | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV100141323; called by muse, mutect2, varscan2
- OR2T1 | c.572C>A p.T191K | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as COSV100822332; called by muse, mutect2, varscan2
- OR2T1 | c.817C>A p.L273I | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100822333, COSV63542946; called by muse, mutect2, varscan2
- OR2T33 | c.402G>T p.M134I | Missense Mutation (SNP) | VAF 54/306 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV100532067; called by muse, varscan2
- OR4A5 | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV60521552; called by muse, mutect2, varscan2
- OR4K13 | c.446A>G p.Y149C | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs192679665, COSV100237776; called by muse, mutect2, varscan2
- OR52B2 | c.964G>C p.G322R | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.311); catalogued as COSV101603953; called by muse, mutect2, varscan2
- OR52E6 | c.922T>G p.F308V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.215); catalogued as COSV100259389; called by muse, mutect2, varscan2
- OR5C1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 47/84 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as rs201590529; called by muse, mutect2, varscan2
- OR5H14 | c.634G>C p.G212R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs1391620357, COSV101454216; called by muse, mutect2, varscan2
- OR5K1 | c.580A>G p.I194V | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.047); catalogued as COSV60304855; called by muse, mutect2, varscan2
- OR5K4 | c.80T>C p.L27P | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100721362; called by muse, mutect2, varscan2
- OR5K4 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272808607, COSV100721363, COSV61584060; called by muse, mutect2, varscan2
- OR5M10 | c.730del p.H244Tfs*2 | Frame Shift Del (DEL) | VAF 18/81 reads (22%) | catalogued as COSV73242353; called by mutect2, varscan2
- OR8B4 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62069398; called by muse, mutect2, varscan2
- OSBPL10 | c.1342G>T p.G448W | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV67340776; called by muse, mutect2, varscan2
- OSBPL2 | c.155C>A p.S52Y (on ENST00000313733 / NM_144498.4; = p.S40Y on NM_014835.4) | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.212); catalogued as COSV100569293; called by muse, mutect2
- OSBPL6 | c.2356G>T p.E786* | Nonsense Mutation (SNP) | VAF 22/145 reads (15%) | catalogued as COSV99507813; called by muse, mutect2, varscan2
- OTOF | c.3257G>A p.G1086E (on ENST00000272371 / NM_194248.3; = p.G339E on NM_004802.4) | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718085; called by muse, mutect2, varscan2
- PAPLN | c.370G>T p.G124W | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99389921; called by muse, mutect2, varscan2
- PAPOLA | c.643C>G p.P215A | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV99354364; called by muse, mutect2, varscan2
- PAQR9 | c.334G>T p.V112L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs911457348, COSV100503839; called by muse, mutect2, varscan2
- PC | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100852275; called by muse, mutect2
- PCDH11X | c.2953A>T p.S985C | Missense Mutation (SNP) | VAF 22/151 reads (15%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs1212781259, COSV100012725; called by muse, mutect2, varscan2
- PCDH11Y | c.3049A>T p.S1017C (on ENST00000400457 / NM_032973.2; = p.S1006C on NM_032971.3) | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV99291830; called by mutect2, varscan2
- PCDH15 | c.4889G>C p.R1630P (on ENST00000644397 / NM_001354429.2; = p.R1572P on NM_001142771.2) | Missense Mutation (SNP) | VAF 74/130 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as rs757319626, COSV100904914; called by muse, mutect2, varscan2
- PCDH15 | c.2143C>A p.P715T | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100222757; called by muse, mutect2, varscan2
- PCDH8 | c.2182G>T p.E728* | Nonsense Mutation (SNP) | VAF 21/56 reads (38%) | catalogued as COSV100131832; called by muse, mutect2, varscan2
- PCDHA8 | c.768C>G p.D256E | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV100970826; called by muse, mutect2, varscan2
- PCDHGA2 | c.942C>G p.F314L | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.02); catalogued as COSV53976968, COSV99541029; called by muse, mutect2, varscan2
- PCDHGB2 | c.824C>A p.A275E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as COSV99541034; called by muse, mutect2, varscan2
- PCDHGB3 | c.2023C>A p.L675I | Missense Mutation (SNP) | VAF 26/126 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV53950491, COSV99541037; called by muse, mutect2, varscan2
- PCF11 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 64/97 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV100018653; called by muse, mutect2, varscan2
- PDE10A | c.1368del p.W456Cfs*60 | Frame Shift Del (DEL) | VAF 31/109 reads (28%) | catalogued as COSV63098575, COSV63106600; called by mutect2, pindel, varscan2
- PDE11A | c.1022C>A p.A341E | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV53704601, COSV99613176; called by muse, mutect2
- PDE5A | c.1697T>A p.L566Q | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99308843; called by muse, mutect2, varscan2
- PDE6A | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV99678134; called by muse, mutect2, varscan2
- PDHA2 | c.586G>T p.A196S | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV54778891, COSV99756713, COSV99757008; called by muse, mutect2, varscan2
- PDHA2 | c.695A>T p.E232V | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV99757012; called by muse, mutect2, varscan2
- PEG3 | c.625A>G p.R209G | Missense Mutation (SNP) | VAF 38/129 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs772421388, COSV99689403; called by muse, mutect2, varscan2
- PGLYRP3 | c.594C>G p.N198K | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.189); catalogued as COSV99319783; called by muse, mutect2, varscan2
- PGM2 | c.526-1G>T p.X176_splice | Splice Site (SNP) | VAF 20/72 reads (28%) | catalogued as COSV101126566, COSV101126603; called by muse, mutect2, varscan2
- PHF19 | c.1719G>T p.E573D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100876383; called by muse, mutect2, varscan2
- PIGQ | c.1598A>G p.Q533R (on ENST00000026218 / NM_148920.3; = p.K554E on NM_004204.5) | Missense Mutation (SNP) | VAF 66/174 reads (38%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.153); catalogued as COSV99216210; called by muse, mutect2, varscan2
- PIGR | c.1975G>T p.G659W | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV100732543; called by muse, mutect2, varscan2
- PIK3C3 | c.2545G>T p.D849Y | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs747035455, COSV100011133; called by muse, mutect2, varscan2
- PILRA | c.899T>A p.V300D | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV99546561; called by muse, mutect2, varscan2
- PKHD1L1 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV101006389; called by muse, mutect2, varscan2
- PKHD1L1 | c.12002C>T p.P4001L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101006390; called by muse, mutect2
- PKNOX2 | c.1016T>A p.F339Y | Missense Mutation (SNP) | VAF 167/224 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV100021130; called by muse, mutect2, varscan2
- PLA2G12A | c.500G>T p.G167V | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697349; called by muse, mutect2, varscan2
- PLB1 | c.417-2A>T p.X139_splice | Splice Site (SNP) | VAF 38/57 reads (67%) | catalogued as rs142867360, COSV100579127; called by muse, mutect2, varscan2
- PLCH2 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs369208976; called by muse, mutect2, varscan2
- PLIN3 | c.1255G>C p.G419R | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99701609; called by muse, mutect2, varscan2
- PLIN5 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 64/197 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV101113570; called by muse, mutect2, varscan2
- PLPPR5 | c.442G>T p.A148S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.264); catalogued as COSV99587497; called by muse, mutect2, varscan2
- PNMA3 | c.342G>C p.R114S | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as COSV100937620; called by muse, mutect2, varscan2
- PNRC1 | c.92C>T p.A31V | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.127); catalogued as COSV100259954; called by muse, mutect2, varscan2
- POGLUT1 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.046); catalogued as COSV99809664; called by muse, mutect2
- POLG | c.724G>T p.A242S | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV99174876; called by muse, mutect2, varscan2
- POLR3A | c.2435G>A p.G812D | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100965706; called by muse, mutect2, varscan2
- POTEH | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.468); catalogued as COSV100625038; called by muse, varscan2
- PPEF2 | c.1644G>T p.R548S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV99714664; called by muse, mutect2, varscan2
- PPFIA4 | c.2242G>T p.A748S (on ENST00000447715; = p.A749S on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV99690682; called by muse, mutect2, varscan2
- PPM1N | c.1255C>A p.P419T | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99839036; called by muse, mutect2, varscan2
- PPP1R3A | c.1457G>C p.R486P | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV52878213, COSV52879159, COSV99493264; called by muse, mutect2, varscan2
- PPP1R3A | c.332A>T p.D111V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV99493269; called by muse, mutect2, varscan2
- PRDM9 | c.547C>A p.L183M | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV99690637; called by muse, mutect2, varscan2
- PRELP | c.959A>G p.N320S | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.42); catalogued as COSV100557866; called by muse, mutect2
- PRG4 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.037); catalogued as COSV63356258; called by muse, varscan2
- PRKCB | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.272); catalogued as COSV57770213; called by muse, mutect2, varscan2
- PRMT6 | c.622T>C p.W208R | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1273636047, COSV100791206; called by muse, mutect2, varscan2
- PRSS1 | c.477G>T p.Q159H | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as COSV61192275; called by muse, mutect2, varscan2
- PRSS27 | c.348C>A p.Y116* | Nonsense Mutation (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100234554, COSV100234595; called by muse, mutect2, varscan2
- PSEN1 | c.770-2A>G p.X257_splice | Splice Site (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99997938; called by muse, mutect2, varscan2
- PSG3 | c.755G>T p.R252M | Missense Mutation (SNP) | VAF 96/195 reads (49%) | SIFT tolerated (0.23); PolyPhen benign (0.026); catalogued as COSV100549070; called by muse, mutect2, varscan2
- PSG4 | c.31C>G p.Q11E | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1470563981, COSV99737314; called by muse, mutect2, varscan2
- PTPRH | c.2138G>T p.G713V | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as rs201897306, COSV99671153; called by muse, mutect2, varscan2
- PTPRN2 | c.2357G>T p.R786L | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101234679; called by muse, mutect2, varscan2
- PTPRN2 | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV101234680; called by muse, mutect2
- PTPRN2 | c.1820C>A p.A607E | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV101234681, COSV67043157; called by muse, mutect2
- PXDN | c.3027G>T p.W1009C | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99413962; called by muse, mutect2, varscan2
- R3HDML | c.662T>A p.M221K | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV99407181; called by muse, mutect2, varscan2
- RAB20 | c.415G>A p.D139N | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99940909; called by muse, mutect2, varscan2
- RAB5IF | c.125del p.L42* | Frame Shift Del (DEL) | VAF 11/72 reads (15%) | catalogued as rs779771385; called by mutect2, pindel
- RABEP2 | c.1063G>T p.A355S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.836); catalogued as COSV100707096; called by muse, mutect2, varscan2
- RALGAPA2 | c.1463C>T p.T488I | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV99173929; called by muse, mutect2
- RALGPS2 | c.1325+1G>T p.X442_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100860621; called by muse, mutect2, varscan2
- RASAL3 | c.201C>A p.F67L | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99484091; called by muse, mutect2, varscan2
- RASGRP1 | c.669G>T p.R223S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV100172062; called by muse, mutect2, varscan2
- RASSF2 | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65082062; called by muse, mutect2, varscan2
- RBM25 | c.1669G>T p.D557Y | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV99998820; called by muse, mutect2, varscan2
- RBM26 | c.2141C>A p.S714Y (on ENST00000438737 / NM_001366735.2; = p.S687Y on NM_022118.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV99936260, COSV99936843; called by muse, mutect2, varscan2
- RBM44 | c.811C>T p.L271F (on ENST00000611254; = p.L905F on NM_001080504.2) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV100389966; called by muse, mutect2, varscan2
- REEP3 | c.113G>T p.W38L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100005104; called by muse, mutect2, varscan2
- RELN | c.1031C>A p.A344D | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.502); catalogued as COSV100634071; called by muse, mutect2, varscan2
- REM1 | c.77G>A p.R26Q | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs575294536, COSV52429544, COSV99147337; called by muse, mutect2
- RESF1 | c.1341A>T p.Q447H | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.929); catalogued as COSV100440413; called by muse, mutect2, varscan2
- RIMBP2 | c.117G>C p.E39D | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.76); catalogued as COSV99899799; called by muse, mutect2, varscan2
- RIMS2 | c.277G>T p.G93C | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101344430, COSV101344581; called by muse, mutect2, varscan2
- RIMS2 | c.1223G>A p.R408Q (on ENST00000666250 / NM_001348490.2; = p.R216Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs376489252, COSV51663807; called by muse, mutect2, varscan2
- RIOK1 | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV53573038; called by muse, mutect2, varscan2
- RLF | c.1355G>T p.R452L | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101035506; called by muse, mutect2, varscan2
- RNF128 | c.122G>T p.S41I | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100176285; called by muse, mutect2, varscan2
- RNF182 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as COSV70368755; called by muse, mutect2, varscan2
- RNGTT | c.865T>C p.Y289H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1338113967, COSV99666821; called by muse, mutect2
- RNGTT | c.863C>A p.P288Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV99666823; called by muse, mutect2
- ROBO1 | c.113A>C p.N38T | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV101517963; called by muse, mutect2, varscan2
- RP1 | c.2309T>A p.V770D | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99607916; called by muse, mutect2, varscan2
- RP1 | c.4686G>A p.M1562I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1459179461, COSV55117580, COSV99607918; called by muse, mutect2, varscan2
- RPS20 | c.177G>C p.K59N | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as COSV99154958; called by muse, mutect2, varscan2
- RRP1B | c.1427G>T p.R476L | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.321); catalogued as COSV100513092; called by muse, mutect2, varscan2
- RTL9 | c.2603C>A p.S868Y | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV101511724; called by muse, mutect2, varscan2
- RTP3 | c.47T>C p.M16T | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.632); catalogued as COSV99946953; called by muse, mutect2, varscan2
- RUNDC3B | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV99713392; called by muse, mutect2, varscan2
- RUNX1T1 | c.1490C>A p.A497E (on ENST00000265814 / NM_001198628.1; = p.A470E on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV56143789, COSV99752876; called by muse, mutect2, varscan2
- RXYLT1 | c.14G>T p.R5L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0.393); catalogued as COSV99706985; called by muse, mutect2, varscan2
- RYR2 | c.2561C>A p.T854K | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV100771274; called by muse, mutect2, varscan2
- RYR2 | c.3488G>T p.G1163V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100771278, COSV63657886; called by muse, mutect2, varscan2
- RYR2 | c.10742G>T p.R3581I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as CM166003, COSV100771279; called by muse, mutect2, varscan2
- RYR2 | c.12178C>A p.Q4060K | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as COSV100771280; called by muse, mutect2, varscan2
- RYR2 | c.12591del p.F4198Lfs*14 | Frame Shift Del (DEL) | VAF 23/111 reads (21%) | catalogued as rs1246253998; called by mutect2, pindel, varscan2
- RYR3 | c.1446G>T p.L482F | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs552954062, COSV101213082, COSV66785690; called by muse, mutect2, varscan2
- RYR3 | c.3649G>T p.G1217C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213084, COSV66776331; called by mutect2, varscan2
- RYR3 | c.10445G>T p.R3482L (on ENST00000389232; = p.R3483L on NM_001036.6) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101213085, COSV66789758; called by muse, mutect2, varscan2
- SALL3 | c.3590A>T p.Q1197L | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101610019; called by muse, mutect2, varscan2
- SCD5 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100124818, COSV60300099; called by muse, mutect2, varscan2
- SCUBE2 | c.1730G>A p.S577N | Missense Mutation (SNP) | VAF 53/195 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100496765; called by muse, mutect2, varscan2
- SEMA6D | c.2127C>A p.D709E (on ENST00000316364 / NM_153618.2; = p.D647E on NM_020858.2) | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.771); catalogued as COSV100317193; called by muse, mutect2, varscan2
- SERAC1 | c.1685-1G>T p.X562_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV100894855; called by muse, mutect2, varscan2
- SERPINA6 | c.1132C>A p.R378S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.062); catalogued as rs1166623585, COSV100448331, COSV58587023; called by muse, mutect2, varscan2
- SERPINA7 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100568375, COSV59665943; called by muse, mutect2, varscan2
- SERPINB10 | c.933G>T p.M311I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.027); catalogued as COSV99449365; called by muse, mutect2, varscan2
- SERPINE1 | c.76C>A p.H26N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV99776749; called by muse, mutect2, varscan2
- SHB | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 110/186 reads (59%) | catalogued as COSV100891066; called by muse, varscan2
- SI | c.3418C>A p.P1140T | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV100013834, COSV100016075; called by muse, mutect2, varscan2
- SI | c.2081C>A p.T694N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100016077; called by muse, varscan2
- SI | c.1792G>C p.A598P | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769057782, COSV100016079; called by muse, mutect2, varscan2
- SIK2 | c.788C>T p.A263V | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV100516308; called by muse, mutect2, varscan2
- SIPA1L2 | c.3266G>T p.R1089L | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.218); catalogued as COSV53393541, COSV99478755; called by muse, mutect2, varscan2
- SIRPB1 | c.842G>T p.G281V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.139); catalogued as COSV53539952, COSV99498463; called by muse, mutect2, varscan2
- SIRPB1 | c.644T>C p.V215A | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.021); catalogued as COSV99498464; called by muse, mutect2, varscan2
- SKIV2L | c.133C>T p.H45Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.149); catalogued as COSV100952802; called by muse, mutect2, varscan2
- SLAMF1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.922); catalogued as COSV99349384; called by muse, mutect2
- SLAMF9 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as rs375532203; called by muse, mutect2, varscan2
- SLC12A5 | c.1238C>T p.P413L (on ENST00000454036 / NM_001134771.2; = p.P390L on NM_020708.5) | Missense Mutation (SNP) | VAF 65/307 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV54792176; called by muse, mutect2, varscan2
- SLC12A8 | c.763G>C p.G255R | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV100102609, COSV58863618; called by muse, mutect2, varscan2
- SLC17A8 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100035652; called by muse, mutect2, varscan2
- SLC1A6 | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV99693877; called by muse, mutect2, varscan2
- SLC22A25 | c.755C>G p.A252G | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100123705; called by muse, mutect2, varscan2
- SLC24A2 | c.212G>C p.S71T | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV99646878; called by muse, mutect2, varscan2
- SLC25A14 | c.965G>A p.R322K | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99502499; called by muse, mutect2, varscan2
- SLC25A39 | c.635G>T p.W212L (on ENST00000377095 / NM_001143780.3; = p.W204L on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.261); catalogued as COSV99835307; called by muse, mutect2, varscan2
- SLC25A48 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.331); catalogued as COSV50850842, COSV50850925; called by muse, mutect2, varscan2
- SLC35F3 | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.194); catalogued as COSV100785411; called by muse, mutect2
- SLC35G3 | c.562T>A p.Y188N | Missense Mutation (SNP) | VAF 150/318 reads (47%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV99268834; called by muse, mutect2, varscan2
- SLC35G5 | c.742A>C p.S248R | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV99644392; called by muse, mutect2, varscan2
- SLC39A1 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.62); PolyPhen benign (0.089); catalogued as COSV100135574; called by muse, mutect2
- SLC6A2 | c.913G>T p.A305S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV99574128; called by muse, mutect2, varscan2
- SLC9C2 | c.2640+1G>T p.X880_splice | Splice Site (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100876828; called by muse, mutect2, varscan2
- SLCO1A2 | c.379T>A p.S127T | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as COSV100262172; called by muse, mutect2, varscan2
- SLCO3A1 | c.1474A>T p.T492S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV100575589; called by muse, mutect2, varscan2
- SLCO5A1 | c.551T>G p.F184C | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99480316; called by mutect2, varscan2
- SLIT2 | c.2619G>A p.W873* | Nonsense Mutation (SNP) | VAF 19/60 reads (32%) | catalogued as COSV99884880; called by muse, mutect2, varscan2
- SLITRK2 | c.2458C>T p.P820S | Missense Mutation (SNP) | VAF 30/47 reads (64%) | SIFT tolerated (0.34); PolyPhen benign (0.076); catalogued as COSV100157889; called by muse, mutect2, varscan2
- SLITRK3 | c.1018C>G p.R340G | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53854970, COSV99579428; called by muse, mutect2, varscan2
- SMCR8 | c.2314T>A p.L772M | Missense Mutation (SNP) | VAF 106/143 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100329166; called by muse, mutect2, varscan2
- SMG7 | c.566A>G p.Y189C | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100750408; called by muse, mutect2, varscan2
- SMR3B | c.104T>A p.L35Q | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV100513397; called by muse, mutect2, varscan2
- SNIP1 | c.803A>T p.E268V | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.082); catalogued as COSV99953179; called by muse, mutect2, varscan2
- SNTG1 | c.1475C>A p.P492H | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV52476543; called by muse, mutect2, varscan2
- SORBS1 | c.3490C>G p.Q1164E | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as COSV99528371; called by muse, mutect2, varscan2
- SORCS1 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV53849202; called by muse, mutect2, varscan2
- SORCS3 | c.2608G>T p.A870S | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.177); catalogued as rs367942325, COSV100863627; called by muse, mutect2, varscan2
- SPATA17 | c.743C>G p.T248S | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV100861200; called by muse, mutect2, varscan2
- SPN | c.545C>A p.T182N | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs778934492, COSV100788826; called by muse, mutect2, varscan2
- SSTR1 | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV99942946; called by muse, mutect2, varscan2
- ST6GAL2 | c.1474G>T p.V492L | Missense Mutation (SNP) | VAF 31/155 reads (20%) | PolyPhen possibly damaging (0.738); catalogued as COSV100699630; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 18/69 reads (26%) | PolyPhen benign (0.159); catalogued as COSV100083968; called by muse, varscan2
- STRADB | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs893272636, COSV99524617; called by muse, mutect2, varscan2
- STXBP6 | c.437C>G p.S146C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV100121930; called by muse, mutect2, varscan2
- SUGCT | c.908T>A p.L303* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV100002742; called by muse, mutect2, varscan2
- SULT1E1 | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV56946046, COSV56947939, COSV99895050; called by mutect2, varscan2
- SVOP | c.1304C>G p.A435G | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.344); catalogued as COSV100139474; called by muse, mutect2
- SYNE2 | c.7045G>C p.A2349P | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as COSV100647988; called by muse, mutect2
- SYT5 | c.709-1G>A p.X237_splice | Splice Site (SNP) | VAF 19/60 reads (32%) | catalogued as COSV100845917; called by muse, mutect2, varscan2
- TAF3 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100720251; called by muse, mutect2, varscan2
- TAGLN3 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs936509112, COSV56326960; called by muse, mutect2, varscan2
- TAS2R41 | c.876C>G p.S292R | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV101281497; called by muse, mutect2, varscan2
- TBC1D26 | c.275A>T p.K92M | Missense Mutation (SNP) | VAF 101/137 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV101343673; called by muse, mutect2, varscan2
- TBC1D5 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.018); catalogued as rs200832725, COSV99511064; called by muse, mutect2, varscan2
- TBX2 | c.1105G>T p.E369* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99538951; called by muse, mutect2
- TCEAL2 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as COSV100216346; called by muse, mutect2, varscan2
- TCEAL5 | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV101013148; called by muse, mutect2, varscan2
- TCERG1L | c.1097T>A p.V366D | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV100894333; called by muse, mutect2, varscan2
- TCHH | c.4450G>C p.D1484H | Missense Mutation (SNP) | VAF 57/299 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.189); catalogued as COSV100915205; called by muse, mutect2, varscan2
- TCHHL1 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV100916556; called by muse, mutect2, varscan2
- TDRD6 | c.2864G>A p.R955K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.08); catalogued as COSV100287832; called by muse, mutect2, varscan2
- TECTA | c.4628C>A p.S1543* | Nonsense Mutation (SNP) | VAF 24/133 reads (18%) | catalogued as COSV50688720, COSV99880290; called by muse, mutect2, varscan2
- TENM3 | c.5208G>A p.M1736I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101305208; called by muse, mutect2, varscan2
- TENT5D | c.322C>A p.L108I | Missense Mutation (SNP) | VAF 27/35 reads (77%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100382808; called by muse, mutect2, varscan2
- TEP1 | c.5722-1G>T p.X1908_splice | Splice Site (SNP) | VAF 32/89 reads (36%) | catalogued as COSV99402476; called by muse, mutect2, varscan2
- TG | c.2468G>C p.S823T | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99601633; called by muse, mutect2, varscan2
- TGM2 | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 71/184 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100821672, COSV63931421; called by muse, mutect2, varscan2
- TIAF1 | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.381); catalogued as COSV100572406; called by muse, mutect2, varscan2
- TIAM1 | c.1220C>A p.A407E | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV54563103, COSV99736234; called by muse, mutect2, varscan2
- TKTL2 | c.483A>T p.E161D | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99761508; called by muse, mutect2, varscan2
- TLL1 | c.1847-1G>T p.X616_splice | Splice Site (SNP) | VAF 16/42 reads (38%) | catalogued as COSV99287777; called by muse, mutect2, varscan2
- TMEM132B | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs550549644, COSV54751336; called by muse, mutect2, varscan2
- TMEM132D | c.2182G>A p.G728R | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV101242929; called by muse, mutect2, varscan2
- TMEM30A | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100034941; called by muse, mutect2, varscan2
- TMEM51 | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 146/322 reads (45%) | catalogued as COSV101051543; called by muse, mutect2, varscan2
- TMPRSS9 | c.2128C>A p.L710M (on ENST00000648592; = p.L676M on NM_182973.2) | Missense Mutation (SNP) | VAF 66/113 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100211476; called by muse, mutect2, varscan2
- TMTC1 | c.1026T>A p.S342R (on ENST00000539277 / NM_001193451.2; = p.S234R on NM_175861.3) | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1313648484, COSV55478255; called by muse, mutect2, varscan2
- TNIK | c.1780C>T p.H594Y | Missense Mutation (SNP) | VAF 99/152 reads (65%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.806); catalogued as rs902718462, COSV99457975; called by muse, mutect2, varscan2
- TNR | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV99690227; called by muse, mutect2, varscan2
- TONSL | c.734G>T p.C245F | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as COSV101340269; called by muse, mutect2, varscan2
- TPST1 | c.830G>T p.G277V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100507188; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1367+1G>T p.X456_splice | Splice Site (SNP) | VAF 31/66 reads (47%) | catalogued as COSV100966930; called by muse, mutect2, varscan2
- TRBV5-1 | c.53C>G p.P18R | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.726); catalogued as rs747848744; called by muse, mutect2, varscan2
- TRBV5-1 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs372712637; called by muse, mutect2, varscan2
- TRDV1 | c.186C>G p.S62R | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.218); catalogued as rs780516377; called by muse, mutect2, varscan2
- TRIM38 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.725); catalogued as COSV100837596, COSV62641940; called by muse, mutect2, varscan2
- TRIM40 | c.591G>T p.R197S (on ENST00000376724; = p.R168S on NM_138700.4) | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.162); catalogued as COSV100325391; called by muse, mutect2, varscan2
- TRIM49 | c.278G>C p.C93S | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99052205; called by muse, mutect2, varscan2
- TRIM58 | c.130T>G p.C44G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV100825163; called by muse, varscan2
- TRIM58 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100825164; called by muse, mutect2, varscan2
- TRIML2 | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 54/159 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV100456159; called by muse, mutect2, varscan2
- TRPA1 | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.166); catalogued as COSV100084492; called by muse, mutect2, varscan2
- TRPC6 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1320932707, COSV100723503, COSV100723668; called by muse, mutect2
- TSACC | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 33/246 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV100966212; called by muse, mutect2, varscan2
- TTC12 | c.444+1G>T p.X148_splice | Splice Site (SNP) | VAF 10/72 reads (14%) | catalogued as rs782075084, COSV100133171; called by muse, mutect2, varscan2
- TTN | c.33396G>T p.E11132D (on ENST00000591111; = p.E10205D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | PolyPhen benign (0.006); catalogued as COSV100618602; called by muse, mutect2, varscan2
- TTN | c.12401T>C p.V4134A (on ENST00000591111; = p.V4088A on NM_003319.4) | Missense Mutation (SNP) | VAF 83/135 reads (61%) | catalogued as rs1428190839, COSV100618004; called by muse, mutect2, varscan2
- TTN | c.845C>A p.S282Y | Missense Mutation (SNP) | VAF 14/108 reads (13%) | PolyPhen probably damaging (0.998); catalogued as rs878981404, COSV100618608; called by muse, mutect2, varscan2
- TUBAL3 | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 47/74 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100990551; called by muse, mutect2, varscan2
- TYRO3 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.001); catalogued as COSV99777744; called by muse, mutect2
- TYRO3 | c.1409G>A p.R470Q | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs754825265, COSV55480495; called by muse, mutect2, varscan2
- UBA7 | c.1195G>T p.G399W | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100339794; called by muse, mutect2, varscan2
- UBA7 | c.1194T>A p.D398E | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV100339796; called by muse, mutect2, varscan2
- UGT1A1 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100530413; called by muse, mutect2, varscan2
- UGT2B15 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100592361; called by muse, mutect2, varscan2
- UGT2B7 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); catalogued as rs112352348, COSV59443023, COSV59444412; called by muse, mutect2, varscan2
- UNC13C | c.993T>A p.F331L | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as COSV99519404; called by muse, mutect2, varscan2
- UNC5C | c.2501C>A p.T834N | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.978); catalogued as COSV101497939; called by muse, mutect2, varscan2
- UNC79 | c.4717G>T p.A1573S (on ENST00000393151 / NM_001346218.2; = p.A1396S on NM_020818.5) | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV56389417, COSV99828427; called by muse, mutect2, varscan2
- USH2A | c.14200C>G p.P4734A | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV100237499; called by muse, mutect2, varscan2
- USH2A | c.12067-1G>A p.X4023_splice | Splice Site (SNP) | VAF 16/93 reads (17%) | catalogued as rs397517977, COSV100237501; called by muse, mutect2, varscan2
- USH2A | c.6302G>T p.S2101I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as CD104119, COSV100237504; called by muse, mutect2, varscan2
- USH2A | c.3382A>T p.T1128S | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100237508; called by muse, mutect2, varscan2
- USP14 | c.915G>T p.L305F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99864217; called by muse, mutect2, varscan2
- USP51 | c.435G>T p.R145S | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.027); catalogued as COSV101540675; called by muse, mutect2, varscan2
- UTS2R | c.365del p.G122Afs*11 | Frame Shift Del (DEL) | VAF 27/72 reads (38%) | catalogued as COSV104399083; called by mutect2, pindel, varscan2
- VAV1 | c.234C>A p.F78L | Missense Mutation (SNP) | VAF 70/119 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100409198, COSV58378081; called by muse, mutect2, varscan2
- VCAM1 | c.1643G>T p.R548M | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54117994; called by muse, mutect2, varscan2
- VCAN | c.4823G>T p.W1608L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99426304; called by muse, mutect2, varscan2
- VIP | c.61T>C p.S21P | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV100923943, COSV65888536; called by muse, mutect2, varscan2
- VIP | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100923944, COSV65889398; called by muse, mutect2, varscan2
- VSTM4 | c.507G>T p.E169D | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV100251846; called by muse, mutect2, varscan2
- VSTM4 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752618813, COSV100039107; called by muse, mutect2, varscan2
- VWA3B | c.2944A>C p.M982L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101346063; called by muse, mutect2, varscan2
- WASHC5 | c.3122T>C p.I1041T | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100572897; called by muse, mutect2, varscan2
- WASHC5 | c.1577A>G p.D526G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100572898; called by muse, mutect2, varscan2
- WDR33 | c.1006G>T p.A336S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.994); catalogued as COSV100460273; called by muse, mutect2, varscan2
- WNT10B | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 14/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs772141128, COSV99975967; called by muse, mutect2, varscan2
- WWOX | c.1193G>T p.W398L | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101283132; called by muse, mutect2, varscan2
- XIRP2 | c.3678A>C p.E1226D (on ENST00000628543; = p.E1401D on NM_152381.6) | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV54696788, COSV54722905, COSV99739657; called by muse, mutect2, varscan2
- ZAN | c.226G>A p.G76R | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs956391790, COSV100769867, COSV61807472; called by muse, varscan2
- ZAN | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61804614; called by muse, varscan2
- ZBBX | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100284324; called by muse, mutect2
- ZBTB17 | c.1420C>T p.L474F | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs1157815147, COSV100999032; called by muse, mutect2, varscan2
- ZBTB24 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 15/133 reads (11%) | catalogued as COSV100018513; called by muse, mutect2, varscan2
- ZBTB46 | c.1031G>T p.G344V | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV55510504, COSV99829336; called by muse, mutect2, varscan2
- ZBTB7B | c.946G>T p.A316S (on ENST00000292176; = p.A350S on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.696); catalogued as COSV99421312; called by muse, mutect2, varscan2
- ZCRB1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as COSV99861310; called by muse, mutect2, varscan2
- ZEB2 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 63/103 reads (61%) | SIFT tolerated (0.34); PolyPhen benign (0.067); catalogued as COSV100356346; called by muse, mutect2, varscan2
- ZFHX4 | c.1793C>A p.P598H | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen probably damaging (0.912); catalogued as COSV99264243; called by muse, mutect2, varscan2
- ZFHX4 | c.2097C>A p.F699L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99264245; called by muse, mutect2, varscan2
- ZFHX4 | c.2098C>A p.R700S | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50501379, COSV50524770; called by muse, mutect2, varscan2
- ZFHX4 | c.2530C>A p.L844M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99264250; called by muse, mutect2, varscan2
- ZFHX4 | c.8221G>T p.D2741Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99264255; called by muse, mutect2, varscan2
- ZFPM2 | c.1598G>T p.S533I | Missense Mutation (SNP) | VAF 71/172 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as COSV101023288, COSV65873983; called by muse, mutect2, varscan2
- ZIM3 | c.487G>T p.V163L | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.146); catalogued as COSV99518258; called by muse, mutect2, varscan2
318 further variants in this file (68 protein-altering or splice-affecting, 224 silent, 26 other) are not listed here.
